Somatic mutation profile of tumor specimen TCGA-55-8208-01A (aliquot TCGA-55-8208-01A-11D-2238-08) from TCGA case TCGA-55-8208, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.1 years (26,716 days).
Specimen TCGA-55-8208-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b8c4f63-879e-4a88-af27-65a0685af755.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8208-10A (Blood Derived Normal), aliquot TCGA-55-8208-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dfce856-565c-41d9-a89f-0a6654675fba

The open-access MAF lists 340 somatic variants for this specimen: 255 protein-altering or splice-affecting, 78 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 224, Silent 78, Nonsense Mutation 20, Splice Site 8, Intron 3, 3'UTR 2, Frame Shift Ins 1, 5'UTR 1, 5'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.3003C>G p.I1001M | Missense Mutation (SNP) | VAF 31/630 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101201259; called by muse, mutect2
- AC008397.2 | c.681C>G p.H227Q | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV99442144; called by muse, mutect2, varscan2
- ACAD11 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV99392537; called by muse, mutect2
- ACAN | c.5716G>A p.G1906R | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100719039; called by muse, mutect2
- ACSM1 | c.1528-1G>A p.X510_splice | Splice Site (SNP) | VAF 15/172 reads (9%) | catalogued as rs759340715, COSV99533334; called by muse, mutect2
- ADAMTS5 | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99538183; called by muse, mutect2
- ADCY10 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 39/559 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100897027; called by muse, mutect2
- ADD3 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV99523658; called by muse, mutect2
- AKIRIN2 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100005288; called by muse, mutect2
- ANKAR | c.3728C>G p.S1243C | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV99854551; called by muse, mutect2
- APOBEC3D | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV53328830, COSV99329136; called by muse, varscan2
- ARRDC3 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99475269; called by muse, mutect2, varscan2
- ARRDC3 | c.1099G>T p.A367S | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99475371; called by muse, mutect2, varscan2
- ASB15 | c.251T>A p.V84D | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV99306905; called by muse, mutect2, varscan2
- ATG7 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100607815; called by muse, mutect2
- ATIC | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 24/277 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV99378107; called by muse, mutect2
- ATL3 | c.310A>G p.T104A | Missense Mutation (SNP) | VAF 54/494 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100219965; called by muse, mutect2, varscan2
- ATP7A | c.4452G>T p.K1484N | Missense Mutation (SNP) | VAF 46/557 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100431475; called by muse, mutect2
- BCAN | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs754520227, COSV100227821; called by muse, mutect2, varscan2
- BCL2L13 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100456377; called by muse, mutect2
- BCO2 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV100730452; called by muse, mutect2
- BPI | c.348C>G p.I116M (on ENST00000262865; = p.I112M on NM_001725.3) | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV53404067; called by muse, mutect2, varscan2
- BPTF | c.2508C>G p.I836M | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100075787; called by muse, mutect2
- C8orf33 | c.551-2A>T p.X184_splice | Splice Site (SNP) | VAF 25/583 reads (4%) | catalogued as COSV100510599; called by muse, mutect2
- CA1 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 23/313 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810303; called by muse, mutect2
- CACNA1E | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1247888338, COSV62388762; called by muse, mutect2, varscan2
- CACNB2 | c.1912G>A p.D638N (on ENST00000324631 / NM_201596.3; = p.D583N on NM_000724.4) | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.285); catalogued as rs142735478, COSV56651738; called by muse, mutect2, varscan2
- CAND1 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.115); catalogued as COSV101598285; called by muse, mutect2
- CAPRIN1 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100404172; called by muse, mutect2
- CCDC120 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100900696; called by muse, mutect2, varscan2
- CCDC88C | c.215A>T p.N72I | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as COSV101104836; called by muse, mutect2
- CCDC91 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60345576; called by muse, varscan2
- CDH18 | c.1630G>T p.D544Y | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99937554; called by muse, mutect2
- CDHR2 | c.2325C>A p.N775K | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV99992067; called by muse, mutect2, varscan2
- CEP63 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 35/488 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as COSV100133037; called by muse, mutect2
- CFAP20DC | c.656C>T p.T219I (on ENST00000482387 / NM_001351530.2; = p.T94I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/415 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV99919372; called by muse, mutect2
- CHAF1A | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100011405, COSV56672655; called by muse, mutect2, varscan2
- CLMN | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV100112802, COSV54189558; called by muse, mutect2, varscan2
- CNKSR2 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV99669469; called by muse, mutect2
- CNR1 | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV100759319; called by muse, varscan2
- COPA | c.3136G>C p.E1046Q | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.825); catalogued as COSV99616570; called by muse, mutect2, varscan2
- CPB1 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV51572659, COSV99294466; called by muse, mutect2
- CPEB4 | c.1457-1G>T p.X486_splice | Splice Site (SNP) | VAF 12/104 reads (12%) | catalogued as COSV99437557; called by muse, mutect2, varscan2
- CPED1 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100121353; called by muse, mutect2
- CPXM2 | c.1618A>T p.T540S | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV99583106; called by muse, mutect2
- CRISPLD2 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99295960; called by muse, mutect2, varscan2
- CSMD3 | c.2203C>G p.P735A (on ENST00000297405 / NM_001363185.1; = p.P631A on NM_052900.3) | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844421; called by muse, mutect2
- CYTH2 | c.817C>T p.R273W (on ENST00000427476; = p.R272W on NM_004228.7) | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1465922638, COSV100287339; called by muse, mutect2
- DAB1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100976548; called by muse, mutect2
- DAO | c.767A>G p.H256R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.755); catalogued as COSV57323793; called by muse, mutect2, varscan2
- DGCR2 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 51/347 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as COSV99593457; called by muse, mutect2, varscan2
- DUSP10 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100100730; called by muse, mutect2
- E2F3 | c.645G>C p.K215N | Missense Mutation (SNP) | VAF 46/568 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100686193; called by muse, mutect2
- EAPP | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs939639524; called by muse, mutect2
- ECHDC1 | c.872G>A p.G291D (on ENST00000531967 / NM_001139510.1; = p.G285D on NM_001002030.2) | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58933704; called by muse, mutect2, varscan2
- EFHB | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as COSV99860112; called by muse, mutect2, varscan2
- EIF3G | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV99461697; called by muse, mutect2, varscan2
- EPHB1 | c.2456C>A p.S819* | Nonsense Mutation (SNP) | VAF 79/627 reads (13%) | catalogued as COSV101212787; called by muse, mutect2, varscan2
- F5 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63126082; called by muse, mutect2, varscan2
- FBN3 | c.1789C>T p.Q597* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99561623; called by muse, mutect2
- FGL1 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as COSV101112500; called by muse, mutect2
- FLG2 | c.838T>C p.C280R | Missense Mutation (SNP) | VAF 21/476 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV101166125; called by muse, mutect2
- FMNL1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100056842; called by muse, mutect2
- FNIP1 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as COSV100330567; called by muse, mutect2, varscan2
- FRS2 | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100166306; called by muse, mutect2
- FRYL | c.8062C>T p.R2688C | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373229077; called by muse, mutect2, varscan2
- FSTL5 | c.2104G>C p.D702H | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100056280, COSV100059885; called by muse, mutect2
- GABRA1 | c.1281C>A p.F427L | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50107413, COSV99196200; called by muse, mutect2
- GAPT | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as rs1345830381, COSV100576346; called by muse, mutect2, varscan2
- GKN1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as rs1173457831, COSV100933607; called by muse, mutect2
- GMIP | c.1459C>G p.L487V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as COSV99179522; called by muse, mutect2, varscan2
- GON4L | c.2004G>C p.E668D | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99675441; called by muse, mutect2, varscan2
- GPR160 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100576172; called by muse, mutect2, varscan2
- GPR174 | c.174G>T p.M58I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99337870, COSV99338336; called by muse, mutect2
- GRIN2D | c.1971C>G p.I657M | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99616842; called by muse, mutect2, varscan2
- GSDME | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100742428; called by muse, mutect2
- GUCY2D | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs61749674, CM002035, COSV54696846; ClinVar: not provided; called by muse, mutect2, varscan2
- HEATR5B | c.5566G>C p.D1856H | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51849210; called by muse, mutect2
- HECTD4 | c.10247G>T p.R3416L | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.999); catalogued as COSV101108312; called by muse, mutect2, varscan2
- HECW2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53669539; called by muse, mutect2, varscan2
- HELZ | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100698995; called by muse, mutect2
- HMCN1 | c.8788-1G>C p.X2930_splice | Splice Site (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99634267; called by muse, mutect2, varscan2
- IGHD | c.685A>T p.S229C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101163009; called by muse, mutect2
- IMPG1 | c.1630G>T p.D544Y | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs1193133824, COSV100886596; called by muse, mutect2, varscan2
- ITGA2B | c.1278G>C p.Q426H | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV52231990, COSV99289175; called by muse, mutect2
- ITLN1 | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 69/633 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.323); catalogued as COSV100406327, COSV58275523, COSV58276567; called by muse, mutect2, varscan2
- KANK1 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs756321528, COSV100620047; called by muse, mutect2, varscan2
- KAT5 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 16/529 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100384033; called by muse, mutect2
- KAT8 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 54/780 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99571738; called by muse, mutect2
- KCNA6 | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99768895; called by muse, mutect2, varscan2
- KCNB1 | c.2287G>C p.E763Q | Missense Mutation (SNP) | VAF 22/656 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.043); catalogued as COSV100870568; called by muse, mutect2
- KCNJ3 | c.446G>C p.R149P | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54534262, COSV99716339; called by muse, mutect2
- KCNMB4 | c.493C>G p.H165D | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99253368; called by muse, mutect2
- KIAA1522 | c.352G>A p.E118K (on ENST00000373480 / NM_001198972.2; = p.E177K on NM_020888.3) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); catalogued as COSV99614993, COSV99615183; called by muse, mutect2
- KIR2DL1 | c.818-1G>C p.X273_splice | Splice Site (SNP) | VAF 14/246 reads (6%) | catalogued as rs752102380, COSV52416247; called by muse, mutect2
- KLHL28 | c.1627G>T p.V543L | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100753244; called by muse, mutect2, varscan2
- KPTN | c.80A>T p.N27I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99645877; called by muse, mutect2
- KRBOX4 | c.30C>G p.F10L | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV99994357; called by muse, mutect2
- LCOR | c.3739C>T p.P1247S | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99617107; called by muse, mutect2
- LONRF3 | c.1923C>A p.S641R (on ENST00000371628 / NM_001031855.3; = p.S600R on NM_024778.5) | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV100504603; called by muse, mutect2
- LRBA | c.6724C>T p.Q2242* | Nonsense Mutation (SNP) | VAF 14/228 reads (6%) | catalogued as COSV100842013; called by muse, mutect2
- LRRC37B | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV58955135; called by muse, mutect2
- LTBP1 | c.1966T>C p.F656L (on ENST00000404816 / NM_206943.4; = p.F330L on NM_000627.4) | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV63194074; called by muse, mutect2, varscan2
- MAGEE2 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV100973193; called by muse, mutect2
- MAK | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 46/641 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100504624; called by muse, mutect2
- MAP10 | c.2818G>A p.D940N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV101406541; called by muse, mutect2
- MDN1 | c.11797G>C p.E3933Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV101021727; called by muse, mutect2
- MED12 | c.1493C>G p.S498* | Nonsense Mutation (SNP) | VAF 31/415 reads (7%) | catalogued as COSV100379504; called by muse, mutect2
- MED12 | c.5981G>T p.R1994L | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV100379505; called by muse, mutect2, varscan2
- MEI1 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100300265; called by muse, mutect2
- MERTK | c.2574A>C p.L858F | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV99775147; called by muse, mutect2
- MROH7 | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100273930, COSV59878621; called by muse, mutect2
- MRPL46 | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 9/263 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100363799; called by muse, mutect2
- MRPS22 | c.673G>A p.D225N (on ENST00000310776 / NM_001363893.1; = p.D226N on NM_020191.4) | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.581); catalogued as COSV100169191, COSV60349083; called by muse, mutect2
- MUC16 | c.4639G>A p.V1547M | Missense Mutation (SNP) | VAF 73/374 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV101201096; called by muse, mutect2, varscan2
- MXRA7 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 21/583 reads (4%) | PolyPhen probably damaging (0.998); catalogued as COSV100869806; called by muse, mutect2
- MYH8 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 55/524 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101238639; called by muse, mutect2, varscan2
- MYO7B | c.3050T>A p.I1017N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101268357; called by muse, mutect2
- MYOM2 | c.3818C>G p.S1273C | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV100038179, COSV50716439; called by muse, mutect2
- NAA30 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 32/739 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100035999; called by muse, mutect2
- NANP | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV100505045; called by muse, mutect2
- NEDD1 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99901245; called by muse, mutect2
- NFKBIE | c.1481A>C p.K494T (on ENST00000275015; = p.K355T on NM_004556.3) | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99241359; called by muse, mutect2
- NLRP5 | c.2224G>C p.G742R | Missense Mutation (SNP) | VAF 67/479 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV101173847; called by muse, mutect2, varscan2
- NR3C1 | c.1523C>G p.S508* | Nonsense Mutation (SNP) | VAF 14/146 reads (10%) | catalogued as COSV99196622; called by muse, mutect2
- NTNG1 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV99638978; called by muse, mutect2, varscan2
- NUDC | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100345701; called by muse, mutect2, varscan2
- NYAP1 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100278648; called by muse, mutect2, varscan2
- OCEL1 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV99285810; called by muse, mutect2
- OR10R2 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.081); catalogued as COSV100936827; called by muse, mutect2
- OR13C9 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99403542; called by muse, mutect2
- OR1M1 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs770869708, COSV101447589, COSV70037005; called by muse, mutect2, varscan2
- OR2J2 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV65848300; called by muse, mutect2
- OR4A16 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.066); catalogued as COSV100125371; called by muse, mutect2, varscan2
- OR4A5 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); catalogued as rs1275698573, COSV100157258; called by muse, mutect2
- OR4N2 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 50/595 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1382697468, COSV60050828; called by muse, mutect2
- OR51D1 | c.59A>G p.H20R | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100712424; called by muse, mutect2
- OR51F2 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 7/158 reads (4%) | catalogued as rs1460499570, COSV59063581; called by muse, mutect2
- OR5K2 | c.853C>A p.L285I | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV101415977; called by muse, mutect2
- OSBP | c.2107C>T p.L703F | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99803314; called by muse, mutect2
- OTOF | c.3568G>A p.V1190M (on ENST00000272371 / NM_194248.3; = p.V443M on NM_004802.4) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99718682; called by muse, mutect2, varscan2
- PADI4 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV100966905; called by muse, mutect2
- PAXIP1 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV101250016; called by muse, mutect2
- PCDHB8 | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 38/1365 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99177266; called by muse, mutect2
- PCDHGA5 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as COSV53920326, COSV53955956; called by muse, mutect2
- PCDHGA6 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV99544939; called by muse, mutect2
- PCLO | c.12332A>T p.E4111V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100436575; called by muse, mutect2
- PHF8 | c.1625G>T p.R542L (on ENST00000357988 / NM_001184896.1; = p.R506L on NM_015107.3) | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100154701, COSV57679411; called by muse, mutect2
- PHYHIPL | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV100874226; called by muse, mutect2
- PIBF1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100411856; called by muse, mutect2
- PIK3C2G | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 25/333 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99853523; called by muse, mutect2
- PIMREG | c.566C>A p.S189* | Nonsense Mutation (SNP) | VAF 9/114 reads (8%) | catalogued as COSV99338911; called by muse, mutect2
- PKD2L2 | c.409C>A p.R137S | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99296607; called by muse, mutect2, varscan2
- PLD1 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774502670, COSV60573445; called by muse, mutect2
- PLEKHA8 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as COSV99322098; called by muse, mutect2
- PLP1 | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 18/499 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100393525; called by muse, mutect2
- POLR3A | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100965784; called by muse, mutect2
- POTEH | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 46/541 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100625189; called by muse, mutect2
- PPM1F | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV99601653; called by muse, mutect2, varscan2
- PRAME | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101287212; called by muse, mutect2, varscan2
- PRB1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 74/655 reads (11%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.113); catalogued as COSV99556014; called by muse, mutect2, varscan2
- PRKAA2 | c.1060G>T p.D354Y | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1355840765, COSV100983032; called by muse, mutect2, varscan2
- PRKCE | c.694-1G>T p.X232_splice | Splice Site (SNP) | VAF 37/328 reads (11%) | catalogued as COSV100079161; called by muse, mutect2, varscan2
- PRKCE | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100079165; called by muse, mutect2, varscan2
- PRKDC | c.6278G>C p.C2093S | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100042369; called by muse, mutect2
- PRLHR | c.402C>A p.C134* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99492927; called by muse, mutect2
- PRMT3 | c.998A>G p.Y333C | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343015550, COSV100424144; called by muse, mutect2, varscan2
- PSD3 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as rs868683143, COSV99676664; called by muse, mutect2
- PSIP1 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as rs138825013, COSV101050992; called by muse, mutect2
- PTCHD3 | c.2252T>C p.I751T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1204836684, COSV101438957; called by muse, mutect2
- PYHIN1 | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.316); catalogued as rs1192812273, COSV100932657; called by muse, mutect2
- RAB4B | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as COSV99648288; called by muse, mutect2, varscan2
- RABEP1 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 6/93 reads (6%) | catalogued as COSV99336940; called by muse, mutect2
- RASGRP2 | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV100818319; called by muse, mutect2
- RB1 | c.455T>A p.L152* | Nonsense Mutation (SNP) | VAF 29/204 reads (14%) | catalogued as COSV99925193; called by muse, mutect2, varscan2
- RNF180 | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99684897; called by muse, mutect2, varscan2
- ROR2 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100996065; called by muse, mutect2, varscan2
- RPS6KL1 | c.1582G>C p.G528R | Missense Mutation (SNP) | VAF 128/516 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV99472094; called by muse, mutect2, varscan2
- RTL9 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 38/664 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV101511771; called by muse, mutect2
- RTL9 | c.3269G>A p.G1090E | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as COSV101511772; called by muse, mutect2
- RTN4RL2 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.412); catalogued as COSV100625479, COSV58652151; called by muse, mutect2
- RUNDC1 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs568593311, COSV100865883; called by muse, mutect2
- RYR2 | c.9734A>C p.Y3245S | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100772265; called by muse, mutect2, varscan2
- SALL3 | c.3644A>G p.Y1215C | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101610042; called by muse, mutect2
- SBNO1 | c.3993G>C p.K1331N (on ENST00000420886; = p.K1330N on NM_018183.5) | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99929566; called by muse, mutect2
- SCAI | c.363G>T p.W121C (on ENST00000336505 / NM_001144877.3; = p.W144C on NM_173690.5) | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100332967; called by muse, mutect2, varscan2
- SCML1 | c.561C>G p.F187L (on ENST00000380041 / NM_001037540.3; = p.F160L on NM_006746.6) | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV101193968, COSV66240517; called by muse, mutect2
- SDS | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99981158; called by muse, mutect2, varscan2
- SELP | c.1861A>T p.R621* | Nonsense Mutation (SNP) | VAF 13/199 reads (7%) | catalogued as COSV99740836; called by muse, mutect2
- SEPTIN7 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100621882; called by muse, mutect2
- SERPINB12 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV54032968, COSV99501868; called by muse, mutect2
- SESTD1 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV100090819; called by muse, mutect2, varscan2
- SH2D3C | c.2158A>T p.K720* (on ENST00000314830 / NM_170600.3; = p.K563* on NM_005489.4) | Nonsense Mutation (SNP) | VAF 12/119 reads (10%) | catalogued as COSV100137329; called by muse, mutect2, varscan2
- SLC7A13 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.621); catalogued as COSV52537214, COSV99879142; called by muse, mutect2
- SLC7A13 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.083); catalogued as COSV99879145; called by muse, mutect2
- SLITRK4 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as COSV100567474; called by muse, mutect2, varscan2
- SMG7 | c.2983G>A p.D995N | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100750524; called by muse, mutect2
- SNRNP200 | c.4966G>T p.V1656L | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100107981; called by muse, mutect2
- SNRNP48 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100673049; called by muse, mutect2
- SNURF | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100577800; called by muse, mutect2
- SP100 | c.1754G>C p.R585T | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.095); catalogued as COSV50974941, COSV99894028; called by muse, mutect2
- SPAG1 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 15/228 reads (7%) | catalogued as COSV99309356; called by muse, mutect2
- STXBP5L | c.253T>G p.L85V | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV56529775; called by muse, mutect2, varscan2
- SWT1 | c.2255A>G p.H752R | Missense Mutation (SNP) | VAF 20/626 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100833491; called by muse, mutect2
- SYNE2 | c.14425G>C p.E4809Q | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV100648362; called by muse, mutect2
- TANC1 | c.1312A>G p.R438G | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV99714959; called by muse, mutect2
- TASOR2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV100050898; called by muse, mutect2
- TAT | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV100587716; called by muse, mutect2
- TBKBP1 | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT tolerated (0.65); PolyPhen benign (0.172); catalogued as rs1206567632, COSV100659218; called by muse, mutect2
- TENM1 | c.6858C>G p.H2286Q | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100950634; called by muse, mutect2
- TEX15 | c.1252A>G p.R418G (on ENST00000256246; = p.R801G on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1393740914, COSV99821951; called by muse, mutect2
- THOC2 | c.2899+2T>C p.X967_splice | Splice Site (SNP) | VAF 16/245 reads (7%) | catalogued as COSV99834004; called by muse, mutect2
- TKTL1 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99474127; called by muse, mutect2
- TLE2 | c.1746C>G p.V582= | Splice Region (SNP) | VAF 6/123 reads (5%) | catalogued as COSV99504606; called by muse, mutect2
- TMEM39A | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100052607; called by muse, mutect2
- TNKS | c.2926C>G p.L976V | Missense Mutation (SNP) | VAF 27/469 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV60068626; called by muse, mutect2
- TSPAN8 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.49); catalogued as rs756170144, COSV99922400; called by muse, mutect2
- TSPEAR | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as rs782571305, COSV100555104; called by muse, mutect2
- TTC27 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 46/436 reads (11%) | catalogued as COSV100513464; called by muse, mutect2
- TTC39B | c.1942T>G p.F648V | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99895950; called by muse, mutect2, varscan2
- TUBA3E | c.326C>A p.T109N | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.569); catalogued as rs192490751; called by muse, mutect2
- TYW1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV55887146; called by muse, mutect2
- UFL1 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV65150360, COSV65150530; called by muse, mutect2, varscan2
- USPL1 | c.2306C>A p.S769Y | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1357326002, COSV99687532; called by muse, mutect2
- UTP18 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99834914; called by muse, mutect2
- VPS13B | c.7018A>T p.R2340* | Nonsense Mutation (SNP) | VAF 6/146 reads (4%) | catalogued as COSV100663133; called by muse, mutect2
- VPS8 | c.2321A>G p.Y774C (on ENST00000625842 / NM_001349294.1; = p.Y772C on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs374826962; called by muse, mutect2, varscan2
- VSIG4 | c.1141C>A p.L381M | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV101038265; called by muse, mutect2, varscan2
- VWA8 | c.1894C>G p.L632V | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV99864887; called by muse, mutect2
- WBP1L | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV100882509; called by muse, mutect2
- WDR33 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV100205352; called by muse, mutect2
- WDR49 | c.594G>C p.M198I (on ENST00000308378 / NM_001366158.1; = p.M539I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV100393649; called by muse, mutect2, varscan2
- WFDC12 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100859104; called by muse, mutect2
- WFDC5 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100332185, COSV57217520; called by muse, mutect2
- XIRP2 | c.1532G>T p.G511V (on ENST00000628543; = p.G686V on NM_152381.6) | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV99746414; called by muse, mutect2
- YWHAQ | c.731A>G p.E244G | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as COSV99431392; called by muse, mutect2, varscan2
- YY1AP1 | c.1159G>A p.E387K (on ENST00000295566 / NM_139118.2; = p.E330K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV55119134, COSV99804551; called by muse, mutect2
- ZFYVE16 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100566609; called by muse, mutect2
- ZNF334 | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100749177; called by muse, mutect2
- ZNF462 | c.2813G>C p.R938T | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99473010; called by muse, mutect2
- ZNF484 | c.1694C>G p.S565* | Nonsense Mutation (SNP) | VAF 10/242 reads (4%) | catalogued as COSV100214830; called by muse, mutect2
- ZNF571 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as COSV100143967; called by muse, mutect2, varscan2
- ZNF622 | c.759C>G p.D253E | Missense Mutation (SNP) | VAF 14/470 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as COSV100433161; called by muse, mutect2
- ZNF675 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as COSV100705159; called by muse, mutect2
- ZNF787 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54419561; called by muse, mutect2, varscan2
- ACACA | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- ARID1A | c.2296dup p.Q766Pfs*51 | Frame Shift Ins (INS) | VAF 31/264 reads (12%) | called by mutect2, pindel, varscan2
- EFEMP1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.026); called by muse, mutect2
- HECTD2 | c.712-1G>C p.X238_splice | Splice Site (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- MRC1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.407); called by muse, mutect2
- PTPRF | c.4966T>C p.F1656L | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- SLC32A1 | c.30del p.N11Tfs*14 | Frame Shift Del (DEL) | VAF 15/111 reads (14%) | called by mutect2, pindel, varscan2
- SPIDR | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 18/304 reads (6%) | called by muse, mutect2
- VN1R5 | c.516G>T p.W172C | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2
- ACSM5 | c.786C>T p.T262= | Silent (SNP) | VAF 28/359 reads (8%) | catalogued as rs752808144, COSV59372901; called by muse, mutect2
- ADAMTS20 | c.4185T>C p.D1395= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV101166379; called by muse, mutect2, varscan2
- ALPK2 | c.2019C>T p.F673= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV100864731; called by muse, mutect2
- AMELX | c.297A>T p.P99= | Silent (SNP) | VAF 32/552 reads (6%) | catalogued as COSV100498931; called by muse, mutect2
- ANK1 | c.4248C>G p.L1416= | Silent (SNP) | VAF 30/735 reads (4%) | catalogued as COSV99226529; called by muse, mutect2
- ANK2 | c.9756A>G p.V3252= | Silent (SNP) | VAF 26/270 reads (10%) | catalogued as COSV100003589; called by muse, mutect2
- ARID1A | c.4611G>A p.Q1537= | Silent (SNP) | VAF 14/141 reads (10%) | catalogued as COSV100252996; called by muse, mutect2, varscan2
- C1orf158 | c.564G>A p.L188= | Silent (SNP) | VAF 34/153 reads (22%) | catalogued as rs1323483632, COSV99847424; called by muse, mutect2, varscan2
- C9 | c.393G>A p.E131= | Silent (SNP) | VAF 34/255 reads (13%) | catalogued as COSV99662409; called by muse, mutect2, varscan2
- CABYR | c.504C>G p.V168= | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as COSV100510149; called by muse, mutect2, varscan2
- CADPS2 | c.1059G>A p.E353= | Silent (SNP) | VAF 30/267 reads (11%) | catalogued as COSV100465222; called by muse, mutect2, varscan2
- CAMTA1 | c.1581C>T p.V527= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV100352053; called by muse, mutect2, varscan2
- CAPN2 | c.1353C>T p.N451= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs929071368, COSV99689176; called by muse, mutect2, varscan2
- CNGB1 | c.2946C>T p.V982= | Silent (SNP) | VAF 22/416 reads (5%) | catalogued as COSV99208099; called by muse, mutect2
- COL10A1 | c.25C>T p.L9= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV99684411; called by muse, mutect2, varscan2
- COL22A1 | c.2325A>G p.E775= | Silent (SNP) | VAF 39/510 reads (8%) | catalogued as COSV100280254; called by muse, mutect2
- COL4A1 | c.3495G>A p.K1165= | Silent (SNP) | VAF 15/196 reads (8%) | catalogued as COSV101011465; called by muse, mutect2
- DIDO1 | c.1629C>T p.A543= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99826799; called by muse, mutect2
- DRD5 | c.138G>A p.L46= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100431987; called by muse, mutect2
- DUSP6 | c.48C>T p.I16= | Silent (SNP) | VAF 10/203 reads (5%) | catalogued as COSV99684127; called by muse, mutect2
- EBF3 | c.576C>G p.L192= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV100799547; called by muse, mutect2
- FNDC4 | c.555G>T p.G185= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as COSV99254021; called by muse, mutect2
- GABRG2 | c.1506C>G p.V502= (on ENST00000361925 / NM_001375343.1; = p.V462= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/470 reads (7%) | catalogued as COSV100729772, COSV100729802; called by muse, mutect2
- GAL3ST1 | c.75C>T p.F25= | Silent (SNP) | VAF 17/188 reads (9%) | catalogued as rs765213740, COSV58892902; called by muse, mutect2
- GGA2 | c.1045C>T p.L349= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100564818; called by muse, mutect2, varscan2
- GJC2 | c.843C>G p.L281= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV100812989; called by muse, mutect2
- GSDME | c.1411C>T p.L471= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV56037875; called by muse, mutect2
- HAS3 | c.534G>A p.V178= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99544643; called by muse, mutect2
- HMCN1 | c.6084G>A p.P2028= | Silent (SNP) | VAF 12/298 reads (4%) | catalogued as rs1341655057; called by muse, mutect2
- HOXC9 | c.687C>G p.L229= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as rs370297998, COSV100327613; called by muse, mutect2, varscan2
- IGKV1D-17 | c.195C>A p.V65= | Silent (SNP) | VAF 57/362 reads (16%) | called by muse, mutect2, varscan2
- KCNH7 | c.1644C>T p.G548= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV59792751; called by muse, mutect2
- KIAA1522 | c.354G>A p.E118= (on ENST00000373480 / NM_001198972.2; = p.E177= on NM_020888.3) | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs768853014, COSV99615000; called by muse, mutect2
- LCK | c.1008G>A p.L336= | Silent (SNP) | VAF 30/514 reads (6%) | catalogued as rs866416120, COSV100288020; called by muse, mutect2
- LGMN | c.351G>A p.L117= | Silent (SNP) | VAF 19/342 reads (6%) | catalogued as COSV100605965; called by muse, mutect2
- LHX8 | c.897C>A p.P299= | Silent (SNP) | VAF 26/319 reads (8%) | catalogued as COSV53957730; called by muse, mutect2
- MAPKBP1 | c.1533G>A p.L511= (on ENST00000456763 / NM_001128608.2; = p.L505= on NM_014994.3) | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as COSV99530020; called by muse, mutect2
- MARCHF6 | c.2241G>A p.L747= | Silent (SNP) | VAF 10/215 reads (5%) | catalogued as COSV99930080; called by muse, mutect2
- MAU2 | c.1272T>C p.S424= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as COSV99449004; called by muse, mutect2, varscan2
- MEGF6 | c.318C>T p.T106= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs553575884, COSV100742289; called by muse, mutect2, varscan2
- MEIOB | c.1122C>T p.L374= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs770995208, COSV100379607, COSV100379922; called by muse, mutect2, varscan2
- NOLC1 | c.2073C>T p.V691= | Silent (SNP) | VAF 39/600 reads (7%) | catalogued as COSV100893761; called by muse, mutect2
- NPHP3 | c.2076G>A p.L692= | Silent (SNP) | VAF 16/338 reads (5%) | catalogued as COSV100447273, COSV58633833; called by muse, mutect2
- OR51Q1 | c.876C>A p.I292= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as COSV100333057; called by muse, mutect2, varscan2
- PABPC4 | c.1275T>A p.P425= | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as COSV100790917; called by muse, mutect2, varscan2
- PCDH15 | c.4776A>T p.P1592= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV100226032; called by muse, mutect2
- PCDHA1 | c.1440G>A p.R480= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as rs781904646, COSV100974437; called by muse, mutect2, varscan2
- PCDHB5 | c.1224G>C p.L408= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as COSV99169361; called by muse, mutect2, varscan2
- PIGZ | c.123C>G p.L41= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as COSV53013209, COSV99433938; called by muse, mutect2, varscan2
- PPM1H | c.1167C>T p.T389= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV99956358; called by muse, mutect2
- PRKCA | c.2004A>G p.L668= | Silent (SNP) | VAF 25/201 reads (12%) | catalogued as rs747321782, COSV101373027; called by muse, mutect2, varscan2
- RDH8 | c.408C>T p.F136= (on ENST00000651512; = p.F116= on NM_015725.4) | Silent (SNP) | VAF 37/162 reads (23%) | catalogued as rs776050013, COSV50678273; called by muse, mutect2, varscan2
- RGL2 | c.624C>T p.I208= | Silent (SNP) | VAF 40/456 reads (9%) | catalogued as COSV101442512; called by muse, mutect2
- RHOT2 | c.627C>T p.L209= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV99554008; called by muse, mutect2
- RNF213 | c.2365C>T p.L789= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as COSV100173851, COSV60630568; called by muse, mutect2
- RNF213 | c.6795A>G p.P2265= | Silent (SNP) | VAF 9/208 reads (4%) | catalogued as COSV100301287; called by muse, mutect2
- RTL8A | c.30C>A p.A10= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as COSV100887750; called by muse, mutect2
- SLC22A8 | c.957G>C p.R319= | Silent (SNP) | VAF 13/302 reads (4%) | catalogued as COSV100268046; called by muse, mutect2
- SLC28A1 | c.1632C>T p.F544= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV54485903; called by muse, mutect2
- SLC32A1 | c.1170G>T p.A390= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV99462122, COSV99462568; called by muse, mutect2, varscan2
- SLC35G3 | c.207G>T p.S69= | Silent (SNP) | VAF 47/359 reads (13%) | catalogued as rs756580342, COSV52012118, COSV99269110; called by muse, mutect2, varscan2
- SLCO2A1 | c.1035C>T p.L345= | Silent (SNP) | VAF 16/353 reads (5%) | catalogued as COSV100189253; called by muse, mutect2
- SMC5 | c.1833G>A p.Q611= | Silent (SNP) | VAF 11/174 reads (6%) | catalogued as COSV100747154; called by muse, mutect2
- SPG7 | c.2007C>T p.F669= (on ENST00000268704; = p.F676= on NM_003119.4) | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as rs746559927, COSV99245342; called by muse, mutect2
- SRCAP | c.4647G>T p.L1549= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV99351083; called by mutect2, varscan2
- SRSF12 | c.750C>T p.S250= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs1315815311, COSV101504993; called by muse, mutect2
- STAG3 | c.2883C>A p.A961= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV100426138; called by muse, mutect2
- TARS3 | c.1755A>C p.L585= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as COSV100254939; called by muse, mutect2
- TEK | c.2088G>A p.Q696= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV101193540; called by muse, mutect2
- TRADD | c.921C>T p.P307= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs746809465, COSV100799670; called by muse, varscan2
- TRIP10 | c.1605G>A p.E535= (on ENST00000313244 / NM_001288962.2; = p.E479= on NM_004240.4) | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV99838169; called by muse, mutect2, varscan2
- TRIP12 | c.798C>T p.F266= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV99389044, COSV99390823; called by muse, mutect2
- UMOD | c.1812C>A p.I604= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV100208603; called by muse, mutect2, varscan2
- USH2A | c.5955G>A p.E1985= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV100240694; called by muse, mutect2
- WFDC5 | c.168C>A p.P56= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100332182; called by muse, mutect2, varscan2
- ZNF236 | c.4521A>G p.A1507= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as rs530113331, COSV99471042; called by muse, mutect2
- ZNF385B | c.1401G>C p.L467= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV61179827; called by muse, mutect2
- ZNF831 | c.1425G>A p.T475= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as COSV64038569; called by muse, mutect2
- CABYR | c.*17-89C>T | Intron (SNP) | VAF 21/252 reads (8%) | catalogued as COSV100112518; called by muse, mutect2
- DCLK1 | c.2058+5095T>C | Intron (SNP) | VAF 14/228 reads (6%) | catalogued as COSV99712637; called by muse, mutect2
- DNAH8 | chr6:38723104 G>C | 5'Flank (SNP) | VAF 9/192 reads (5%) | catalogued as COSV100546842, COSV59427323; called by muse, mutect2
- MBD1 | c.*153C>G | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs1399914407, COSV99497043; called by muse, mutect2
- PLPP6 | c.*2A>G | 3'UTR (SNP) | VAF 22/318 reads (7%) | catalogued as COSV99795089; called by muse, mutect2
- TTN | c.10360+1629G>A | Intron (SNP) | VAF 18/281 reads (6%) | catalogued as COSV100611773; called by muse, mutect2
- WDR92 | c.-73G>C | 5'UTR (SNP) | VAF 10/89 reads (11%) | catalogued as rs986312298, COSV99718441; called by muse, mutect2
